FM case AD8110 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/43dbd510-bfe5-46fd-9833-1ee4dc04d967

Male, 70.5 years: Carcinoma, NOS (ICD-O-3 8010/3) of the esophagus; metastasis biopsied or resected from the cardia. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
